Somatic mutation profile of tumor specimen TCGA-23-1117-01A (aliquot TCGA-23-1117-01A-02W-0488-09) from TCGA case TCGA-23-1117, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 43.0 years (15,690 days).
Specimen TCGA-23-1117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5c9a363-a597-4e61-ab3c-60914248a109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1117-10A (Blood Derived Normal), aliquot TCGA-23-1117-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1be0a8dc-0c47-4f40-82f3-db67307d337a

The open-access MAF lists 134 somatic variants for this specimen: 96 protein-altering or splice-affecting, 31 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 31, Nonsense Mutation 5, Intron 4, In Frame Del 3, Frame Shift Del 3, Splice Site 2, 3'Flank 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs864321715, CM161051, COSV59247929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 132/279 reads (47%) | catalogued as rs111033334, CM071124, COSV56408694; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAMP | c.760A>T p.K254* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV50308909; called by muse, varscan2
- AGXT2 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51488924; called by muse, mutect2, varscan2
- ANPEP | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV100262571; called by muse, varscan2
- AOC3 | c.1301A>T p.Q434L | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as COSV53828055; called by muse, mutect2, varscan2
- ARHGEF15 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as rs1421216121, COSV62725918; called by muse, mutect2, varscan2
- ATP2B3 | c.3646G>A p.V1216M | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1557022577, COSV54856172; called by muse, mutect2, varscan2
- BACE1 | c.1256C>G p.A419G | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56120292; called by muse, mutect2, varscan2
- C4BPB | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV54692207; called by muse, mutect2, varscan2
- CCDC69 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV62599402, COSV62600429; called by muse, mutect2, varscan2
- CCDC7 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as rs1462957448, COSV56548750; called by muse, mutect2, varscan2
- CDC6 | c.1335G>T p.R445S | Missense Mutation (SNP) | VAF 209/289 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV52931094; called by muse, mutect2, varscan2
- CEP57L1 | c.1016+1G>A p.X339_splice | Splice Site (SNP) | VAF 26/211 reads (12%) | catalogued as COSV61245587; called by muse, mutect2, varscan2
- COL15A1 | c.2758A>C p.K920Q | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66647862; called by muse, mutect2, varscan2
- COL4A4 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 107/174 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61634752; called by muse, mutect2, varscan2
- COL4A5 | c.3325C>A p.P1109T | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100086384; called by muse, mutect2
- DIPK2A | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 172/329 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV59857195, COSV59858050; called by muse, mutect2, varscan2
- DSG3 | c.2621C>A p.S874Y | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV57128332; called by muse, mutect2, varscan2
- EAPP | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 100/151 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV51652729; called by muse, mutect2, varscan2
- ETS2 | c.1066G>T p.G356C | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV62873759; called by muse, mutect2, varscan2
- EXOSC2 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV64910759; called by muse, mutect2, varscan2
- FAM217B | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as rs140439668, COSV100674372; called by muse, mutect2
- FAT1 | c.12013G>T p.V4005L | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV101498922; called by muse, mutect2
- FBLN2 | c.3302C>A p.A1101E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55488748; called by muse, mutect2, varscan2
- FBXO34 | c.1960T>A p.Y654N | Missense Mutation (SNP) | VAF 82/135 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58256095; called by muse, mutect2, varscan2
- FBXW10 | c.1122G>C p.K374N | Missense Mutation (SNP) | VAF 231/373 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV57320347; called by muse, mutect2, varscan2
- GABPA | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61397139; called by mutect2, varscan2
- GLI2 | c.4505G>A p.G1502D (on ENST00000361492 / NM_001374353.1; = p.G1519D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs745550412, COSV58047780; called by muse, mutect2, varscan2
- HMCN1 | c.15493G>T p.D5165Y | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.913); catalogued as COSV54924652; called by muse, mutect2, varscan2
- IL1RAPL1 | c.935A>C p.E312A | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56284928; called by muse, mutect2
- IZUMO1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1330155998, COSV55808428; called by muse, mutect2
- KCNA10 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.49); catalogued as COSV63905090; called by muse, mutect2, varscan2
- KCNA3 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV63902053; called by muse, mutect2
- LCOR | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV63631812; called by muse, mutect2, varscan2
- LVRN | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 184/489 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV63497939; called by muse, mutect2, varscan2
- MAPKAPK2 | c.564G>A p.K188= | Splice Region (SNP) | VAF 27/230 reads (12%) | catalogued as COSV99685713; called by muse, mutect2, varscan2
- MARCHF2 | c.245G>C p.C82S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV53105470, COSV53106173; called by muse, mutect2, varscan2
- MAST2 | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 4/92 reads (4%) | catalogued as COSV100787809; called by muse, mutect2
- MS4A2 | c.713T>C p.M238T | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370005134, COSV54013371; called by muse, mutect2, varscan2
- MTTP | c.2615A>T p.Q872L | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55508554; called by muse, mutect2, varscan2
- NUP54 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV53576733; called by muse, mutect2, varscan2
- OR5L2 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.097); catalogued as rs144590289; called by muse, mutect2
- PASD1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 206/988 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1432580716, COSV64856765; called by muse, mutect2, varscan2
- PIKFYVE | c.4588C>G p.L1530V | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV52246168; called by muse, mutect2, varscan2
- PLEKHA5 | c.3115C>G p.Q1039E | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1565671138, COSV54708284; called by muse, mutect2, varscan2
- PNMA5 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as COSV100721571; called by muse, mutect2
- PPP1R10 | c.981C>A p.S327R | Missense Mutation (SNP) | VAF 119/206 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV64740039; called by muse, mutect2, varscan2
- PRAMEF20 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV57081043; called by muse, mutect2, varscan2
- PRICKLE2 | c.2038C>A p.L680I (on ENST00000295902; = p.L624I on NM_198859.4) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as COSV55769947; called by muse, mutect2, varscan2
- PRPF40A | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV58443645; called by muse, mutect2, varscan2
- PSEN2 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as rs1434992855, COSV100422790; called by muse, mutect2
- RASGRF1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV69181679; called by muse, mutect2, varscan2
- RNASEL | c.664A>T p.T222S | Missense Mutation (SNP) | VAF 140/292 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.04); catalogued as COSV62377524; called by muse, mutect2, varscan2
- RNF20 | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 57/355 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV66661937; called by muse, mutect2, varscan2
- RTN4 | c.3014-2A>G p.X1005_splice (on ENST00000337526 / NM_020532.5; = p.X12_splice on NM_007008.3) | Splice Site (SNP) | VAF 10/67 reads (15%) | catalogued as COSV58271689; called by muse, mutect2, varscan2
- RYR1 | c.14A>T p.E5V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV62105021; called by muse, mutect2, varscan2
- SCEL | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62994175; called by muse, mutect2, varscan2
- SDK2 | c.5092G>T p.V1698F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV66192504; called by muse, mutect2, varscan2
- SEMA6A | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57315325; called by muse, mutect2
- SERPINB11 | c.1118T>A p.F373Y | Missense Mutation (SNP) | VAF 285/422 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66957431, COSV66957524; called by muse, mutect2, varscan2
- SLAMF9 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100928168, COSV63637040; called by muse, mutect2, varscan2
- SLC24A2 | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 116/170 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53870003, COSV53871202; called by muse, mutect2, varscan2
- SLC25A32 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 61/555 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV52568651; called by muse, mutect2, varscan2
- SMTNL1 | c.1285G>T p.V429L (on ENST00000399154; = p.V466L on NM_001105565.2) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV54702457; called by muse, mutect2
- SMYD5 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99242684; called by muse, mutect2, varscan2
- STIP1 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100534780; called by muse, mutect2
- TARDBP | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs1358405889, COSV53570753; called by muse, mutect2, varscan2
- TCF4 | c.1972G>T p.G658* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as rs1555707632, COSV61902607; called by muse, mutect2, varscan2
- TMEM94 | c.1012A>C p.T338P | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV100049971; called by muse, varscan2
- TMOD4 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 161/640 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54860816; called by muse, mutect2, varscan2
- TRPC3 | c.2348T>C p.V783A (on ENST00000379645 / NM_001366479.2; = p.V710A on NM_003305.2) | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1386284134, COSV53378766; called by muse, mutect2, varscan2
- TSGA13 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.215); catalogued as COSV58406327; called by muse, mutect2, varscan2
- TTN | c.4674T>G p.F1558L (on ENST00000591111; = p.F1512L on NM_003319.4) | Missense Mutation (SNP) | VAF 17/211 reads (8%) | PolyPhen benign (0.179); catalogued as COSV59979375; called by muse, mutect2
- UIMC1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779796802, COSV65893244; called by mutect2, varscan2
- VSIR | c.520G>C p.A174P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56479880; called by muse, mutect2, varscan2
- WNK1 | c.4052C>T p.A1351V (on ENST00000315939 / NM_018979.4; = p.A1104V on NM_014823.3) | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV60041155; called by muse, mutect2, varscan2
- YTHDF2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370101470; called by muse, varscan2
- ZNF461 | c.1100G>T p.R367M | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV64454570; called by muse, mutect2, varscan2
- ZNF496 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs774017482, COSV54180391, COSV99665722; called by muse, mutect2, varscan2
- ZNF691 | c.136G>A p.E46K (on ENST00000372502; = p.E15K on NM_015911.3) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV65289556; called by muse, mutect2, varscan2
- ZNF91 | c.3152A>G p.K1051R | Missense Mutation (SNP) | VAF 6/170 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1450649258, COSV100322099, COSV56081234; called by muse, mutect2
- ZSCAN20 | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.129); catalogued as COSV63683889; called by muse, mutect2, varscan2
- ZSCAN20 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100792477; called by muse, mutect2
- ARHGAP24 | c.1289G>T p.S430I (on ENST00000395184 / NM_001025616.3; = p.S337I on NM_031305.3) | Missense Mutation (SNP) | VAF 18/405 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- CNOT3 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HBS1L | c.872_900del p.T291Kfs*15 | Frame Shift Del (DEL) | VAF 164/462 reads (35%) | called by mutect2, pindel, varscan2
- HORMAD1 | c.776_784del p.V259_D261del | In Frame Del (DEL) | VAF 35/333 reads (11%) | called by mutect2, pindel, varscan2
- IGHV4-61 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- KANK1 | c.1800_1828del p.T602Rfs*25 | Frame Shift Del (DEL) | VAF 5/65 reads (8%) | called by mutect2, pindel
- LRRC23 | c.260_262del p.L87del | In Frame Del (DEL) | VAF 67/548 reads (12%) | called by pindel, varscan2
- MYH2 | c.3965A>G p.K1322R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.17); called by muse, mutect2
- PCDHB4 | c.1334A>T p.D445V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF20 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 328/1317 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- THSD7A | c.3284_3316del p.N1095_S1105del | In Frame Del (DEL) | VAF 90/447 reads (20%) | called by mutect2, pindel
- TP53 | c.430_460del p.Q144Afs*16 | Frame Shift Del (DEL) | VAF 39/68 reads (57%) | called by mutect2, pindel, varscan2
- ACAN | c.252A>G p.V84= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV61365910; called by muse, mutect2, varscan2
- ANPEP | c.429A>G p.G143= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55593522; called by muse, varscan2
- CCDC33 | c.1491G>A p.L497= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as rs778477758, COSV51502190; called by muse, mutect2, varscan2
- CDC6 | c.336A>C p.L112= | Silent (SNP) | VAF 146/296 reads (49%) | catalogued as COSV52931088; called by muse, mutect2, varscan2
- CDH8 | c.1167G>T p.P389= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV54854562, COSV54886658; called by muse, mutect2, varscan2
- CPN2 | c.963A>G p.S321= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV60471199; called by muse, mutect2, varscan2
- CUX1 | c.1806T>G p.R602= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV52909296; called by muse, mutect2, varscan2
- DGKA | c.942G>A p.A314= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as COSV59387716; called by muse, mutect2, varscan2
- EML4 | c.1236T>A p.V412= | Silent (SNP) | VAF 164/301 reads (54%) | catalogued as COSV59302502; called by muse, mutect2, varscan2
- FAM153B | c.312A>T p.T104= (on ENST00000253490; = p.T27= on NM_001265615.1) | Silent (SNP) | VAF 57/551 reads (10%) | catalogued as COSV53687682; called by muse, mutect2, varscan2
- IRAG1 | c.486G>A p.A162= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs753874354, COSV70212391; called by muse, mutect2, varscan2
- IZUMO1 | c.729C>G p.A243= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV55807031, COSV99710557; called by muse, mutect2
- KRT40 | c.102C>T p.L34= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as rs376601595, COSV66696396; called by muse, mutect2
- KRT5 | c.688C>T p.L230= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as COSV99357776; called by muse, mutect2
- MSH2 | c.1227G>A p.Q409= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs759098126, COSV51882569; called by muse, mutect2, varscan2
- OR51T1 | c.747A>C p.A249= | Silent (SNP) | VAF 161/243 reads (66%) | catalogued as rs1442921225, COSV59027109; called by muse, mutect2, varscan2
- OR5M1 | c.582C>G p.V194= | Silent (SNP) | VAF 71/216 reads (33%) | catalogued as COSV73202310; called by muse, mutect2, varscan2
- OR6X1 | c.237G>A p.L79= | Silent (SNP) | VAF 89/186 reads (48%) | catalogued as COSV60010228; called by muse, mutect2, varscan2
- PCDHGB4 | c.1440G>T p.G480= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV53999456; called by muse, mutect2, varscan2
- PPP4R1 | c.123A>G p.Q41= (on ENST00000400556 / NM_001042388.3; = p.Q24= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as COSV99553103; called by muse, mutect2
- RIMS1 | c.2967T>C p.S989= | Silent (SNP) | VAF 48/201 reads (24%) | catalogued as COSV53472693; called by muse, mutect2, varscan2
- RPN2 | c.1701C>T p.V567= | Silent (SNP) | VAF 76/220 reads (35%) | catalogued as rs757241492, COSV52907759; called by muse, mutect2, varscan2
- SIPA1L3 | c.2607G>A p.G869= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV55920758; called by muse, mutect2, varscan2
- SOS2 | c.3600G>T p.L1200= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV53571723; called by muse, mutect2, varscan2
- SPATA5L1 | c.2184G>A p.P728= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs773984786, COSV59745333; called by muse, mutect2, varscan2
- SPG11 | c.337C>T p.L113= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs878855128, COSV55999658; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYT9 | c.1437G>A p.K479= | Silent (SNP) | VAF 124/173 reads (72%) | catalogued as COSV59622722; called by muse, mutect2, varscan2
- TMEM119 | c.576C>T p.G192= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs147107990; called by muse, mutect2, varscan2
- UBE2E3 | c.66G>T p.A22= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV66585836; called by muse, mutect2
- UNK | c.1915C>T p.L639= | Silent (SNP) | VAF 2/9 reads (22%) | called by muse, mutect2
- VWF | c.1599C>T p.D533= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV54629257; called by muse, mutect2, varscan2
- DCT | c.1179+7472T>C | Intron (SNP) | VAF 8/206 reads (4%) | catalogued as COSV100986253; called by muse, mutect2
- GHRH | c.-2G>C | 5'UTR (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99411090; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442744 del AAAGAAGGAATAT | 3'Flank (DEL) | VAF 42/139 reads (30%) | called by mutect2, pindel, varscan2
- NRG1 | c.502+31233G>T | Intron (SNP) | VAF 76/154 reads (49%) | catalogued as COSV55170015; called by muse, mutect2, varscan2
- RAB3GAP2 | c.811+1619G>C | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as COSV52966661; called by muse, mutect2
- SCAI | c.99-10019A>T | Intron (SNP) | VAF 47/227 reads (21%) | catalogued as COSV60615858; called by muse, mutect2, varscan2
- TRAJ12 | chr14:22536185 C>A | 3'Flank (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
